Gene-level copy-number profile of tumor specimen TCGA-23-1119-01A from TCGA case TCGA-23-1119, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 64.8 years (23,686 days).
Specimen TCGA-23-1119-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.d8df3e6b-5174-4a19-9382-786b168a0afe.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,636 have no estimate.
https://portal.gdc.cancer.gov/files/14da55e5-2311-480a-b3bf-fa5c40ab18ae

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 13; copy number 3: 8; copy number 4: 2,443; copy number 5: 7,636; copy number 6: 10,726; copy number 7: 1,612; copy number 8: 7,754; copy number 9: 8,794; copy number 10: 10,226; copy number 11: 740; copy number 12: 2,143; copy number 13: 538; copy number 14: 1,522; copy number 15: 801; copy number 16: 17; copy number 17: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-23-1119-01): tumor purity 0.35, ploidy 8.01, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 2,892 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,272,182–117,549,922, 5 genes, copy number 13 (within-gene range 7–13): LINC01525, AL358072.1, MAN1A2, AL157902.2, VPS25P1.
- chr2:136,765,545–138,307,970, 8 genes, copy number 14 (within-gene range 9–14): THSD7B, RNA5SP105, Y_RNA, HNMT, LINC01832, RPL15P5, YWHAEP5, IDI1P1.
- chr3:133,573,686–197,888,436, 1,105 genes, copy number 14 (within-gene range 5–14) (broad region; genes not listed).
- chr8:43,093,498–53,712,896, 134 genes, copy number 13 (broad region; genes not listed).
- chr8:55,067,585–77,537,290, 338 genes, copy number 13 (within-gene range 5–13) (broad region; genes not listed).
- chr8:90,791,741–144,261,940, 818 genes, copy number 15–16 (within-gene range 5–16) (broad region; genes not listed).
- chr12:752,579–9,010,760, 298 genes, copy number 14 (within-gene range 8–14) (broad region; genes not listed).
- chr12:9,148,840–9,208,395, 1 gene, copy number 14 (within-gene range 8–14): PZP.
- chr12:9,228,533–11,514,136, 110 genes, copy number 14 (broad region; genes not listed).
- chr19:11,296,139–12,140,355, 61 genes, copy number 13 (within-gene range 10–13) (broad region; genes not listed).
- chr20:31,257,664–31,450,257, 14 genes, copy number 17: DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
